TARGET case TARGET-40-NAAHCM — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/58138daa-ac9d-5364-b6a8-aef39fa540bc

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 14 years; Vital status: Dead; Days to death: 542 days (1.5 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.0; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 14.8 years (5,408 days); Year of diagnosis: 2004; Metastasis at diagnosis: No Metastasis; Days to last follow up: 542 days (1.5 years).
   Treatment given: Protocol identifier: BCM.

Follow-up (1 entry)
- Days to follow up: 542 days (1.5 years); Days to first event: 542 days (1.5 years); First event: Death; Year of follow up: 2005.

Biospecimens (1 sample)
- Sample TARGET-40-NAAHCM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 542
- Protocol: BCM
- Disease at diagnosis: Non-metastatic
- Primary tumor site: Arm/hand
- Specific tumor site: Humerus
- Specific tumor region: Proximal
- Histologic response: Stage 1/2 (0-90 % necrosis)
